Somatic mutation profile of tumor specimen BA2483D (aliquot aq-BA2483D) from BEATAML1.0 case 2172, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.8 years (23,301 days).
Specimen BA2483D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de4eb578-e348-4c19-b736-61c81e69bba7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2042D (Solid Tissue Normal), aliquot aq-BA2042D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88889829-236b-40d7-ab11-bcf125ccc0c4

The open-access MAF lists 30 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, Intron 2, Nonsense Mutation 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- INPPL1 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 29/129 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53353022, COSV99995692; called by muse, mutect2, varscan2
- WT1 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 10/212 reads (5%) | catalogued as rs1423753702, CM971594, COSV60067818, COSV60068249, COSV60071382, COSV60073329, COSV60074859, COSV60075137; ClinVar: pathogenic; called by muse, mutect2
- ADARB2 | c.1973G>C p.R658T | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.055); catalogued as COSV104430295, COSV67182732; called by muse, mutect2, varscan2
- DSTYK | c.2012A>G p.N671S | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764174507, COSV65688612; called by muse, mutect2, varscan2
- FLT3 | c.1780T>A p.F594I | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV54051445, COSV54057242, COSV54063712; called by muse, mutect2, varscan2
- GRM3 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1365944007, COSV64467506, COSV64477994; called by muse, mutect2, varscan2
- MUC3A | c.9104C>T p.S3035L | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); catalogued as rs985748159; called by muse, varscan2
- PCDHA5 | c.1723G>T p.A575S | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as rs1554129382, COSV100972409, COSV65353946; called by muse, varscan2
- RYR3 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs776257846, COSV66793170; called by muse, mutect2, varscan2
- SETD2 | c.4877T>C p.F1626S | Missense Mutation (SNP) | VAF 93/214 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57437059; called by muse, mutect2, varscan2
- SORCS2 | c.2516G>A p.R839Q | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs753277765; called by muse, varscan2
- SPTB | c.6776+8C>T | Splice Region (SNP) | VAF 119/265 reads (45%) | catalogued as rs772384819; called by muse, mutect2, varscan2
- WT1 | c.1214-1G>A p.X405_splice | Splice Site (SNP) | VAF 91/302 reads (30%) | catalogued as COSV60071959, COSV60081752; called by muse, mutect2, varscan2
- WT1 | c.959T>A p.L320* | Nonsense Mutation (SNP) | VAF 81/190 reads (43%) | catalogued as COSV60083321; called by mutect2, varscan2
- EFTUD2 | c.2716A>G p.I906V | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.034); called by muse, mutect2
- HERPUD1 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by mutect2, varscan2
- NCAPD3 | c.3878G>T p.C1293F | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.031); called by muse, mutect2
- SACS | c.8729A>G p.N2910S | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- STK24 | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); called by muse, varscan2
- UBR5 | c.824T>G p.I275S | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ULK1 | c.2443A>G p.I815V | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, varscan2
- CPT1B | c.2139C>T p.G713= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs1307502399, COSV56417614; called by muse, mutect2
- EGF | c.1636C>A p.R546= | Silent (SNP) | VAF 81/243 reads (33%) | catalogued as rs756376698; called by muse, mutect2, varscan2
- IRX6 | c.186G>A p.P62= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV99306903; called by muse, mutect2, varscan2
- PABPC4L | c.813A>G p.R271= | Silent (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- SMG7 | c.2529G>A p.Q843= | Silent (SNP) | VAF 82/178 reads (46%) | called by muse, mutect2, varscan2
- VWDE | c.177C>G p.L59= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as rs780638670; called by muse, mutect2, varscan2
- WNK2 | c.2067C>T p.P689= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs372392898, COSV52936882; called by muse, mutect2, varscan2
- ABI3BP | c.1576+6256G>A | Intron (SNP) | VAF 28/79 reads (35%) | catalogued as rs538665614; called by muse, mutect2, varscan2
- CADM1 | c.1078+11167C>T | Intron (SNP) | VAF 55/186 reads (30%) | catalogued as rs751019520; called by muse, mutect2, varscan2
